Somatic mutation profile of tumor specimen 0DH5VR from CCDI case PBBTUE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 0.4 years (162 days).
Specimen 0DH5VR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86b2296d-3fa3-4217-8373-bf465a23d1f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH5U8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06d4c0eb-de32-4a30-8698-c28a42c46009

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Frame Shift Del 1, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOOL | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 28/518 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.227); catalogued as rs1233744069; called by muse, mutect2
- CD99L2 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 377/819 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557418987, COSV60935281; called by muse, mutect2, varscan2
- HS3ST1 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 92/589 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1459315322; called by muse, mutect2, varscan2
- KNDC1 | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 66/523 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.186); catalogued as rs747407995, COSV100465578, COSV58843536; called by muse, mutect2, varscan2
- ADORA1 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 18/578 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- REST | c.1045del p.R349Afs*32 | Frame Shift Del (DEL) | VAF 224/894 reads (25%) | called by mutect2, varscan2
- INSR | c.2067C>T p.F689= | Silent (SNP) | VAF 392/815 reads (48%) | catalogued as rs776263155; called by muse, mutect2, varscan2
- CYTH3 | c.-11G>A | 5'UTR (SNP) | VAF 125/314 reads (40%) | called by muse, mutect2, varscan2
